Gene-level copy-number profile of tumor specimen ALCH-B1UH-TTP1-A from ALCHEMIST case ALCH-B1UH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,364 days).
Specimen ALCH-B1UH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 396fbfee-6568-4273-a11a-61ca934a41bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/96dfdd12-fad7-4b17-ad79-d4720dad3cdb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 9,677; copy number 2: 48,697; copy number 3: 433; copy number 4: 77; copy number 5: 2; copy number 8: 2; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:114,657,949–114,658,062, 1 gene: Y_RNA.
- chr12:116,482,073–116,536,518, 2 genes: LINC02457, LINC00173.
- chr12:120,941,728–120,980,965, 1 gene (within-gene range 0–1): HNF1A-AS1.
- chr12:121,777,754–121,803,403, 1 gene (within-gene range 0–1): RHOF.
- chr12:121,800,797–121,832,656, 2 genes (within-gene range 0–1): AC084018.2, SETD1B.
- chr17:16,414,524–16,437,003, 3 genes: AC093484.2, TRPV2, AC093484.1.
- chr17:16,439,505–16,441,298, 4 genes (within-gene range 0–2): SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr17:63,430,468–63,455,817, 3 genes (within-gene range 0–3): AC005828.4, CYB561, AC005828.5.
- chr18:12,407,896–12,432,238, 1 gene: PRELID3A.
- chr19:56,127,236–56,185,775, 4 genes: AC024580.2, ZNF444, AC024580.1, GALP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,166,932–1,208,962, 1 gene, copy number 5 (within-gene range 2–5): SPON2.
- chr4:1,210,120–1,218,591, 1 gene, copy number 5 (within-gene range 1–5): CTBP1-AS.
- chr21:43,414,483–43,479,534, 4 genes, copy number 8–23: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,847. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
